TARGET case TARGET-30-PAIWVG — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Retroperitoneum and peritoneum. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/2409bf38-6bd0-5f4a-a636-a49b61622668

Demographics
Sex at birth: female; Race: white; Vital status: Dead.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 1.8 years (645 days); Year of diagnosis: 2000; Days to last follow up: 1,624 days (4.4 years); INSS stage: Stage 4.

Biospecimens (2 samples)
- Sample TARGET-30-PAIWVG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAIWVG-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
